RC case RC-B65A — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a9ef923d-4e8f-42de-ae19-6323f79c8e55

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1964; Vital status: Dead; Days to death: 168 days; Year of death: 2020; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Prolymphocytic leukemia, T-cell type: ICD-O-3 morphology code: 9834/3; ICD-10 code: C84; Tissue or organ of origin: Lymph node, NOS; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 55.0 years (20,094 days); Year of diagnosis: 2019; Method of diagnosis: Core Biopsy; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): Low-Intermediate Risk; Sites of involvement: Lymph node, NOS / Lymph Node, Para-Aortic / Lymph Node, Retroperitoneal / Ascites / Peritoneum, NOS / Bone marrow / Liver / Peripheral blood / Pleura / Spleen.
   Pathology details: Bone marrow malignant cells: Yes; Greatest tumor dimension: 4.7 cm; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Vincristine; Initial disease status: Initial Diagnosis; Regimen or line of therapy: EPOCH; Days to treatment start: 18 days; Days to treatment end: 22 days; Number of cycles: 1; Reason treatment ended: Other; Timepoint category: First Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Alemtuzumab; Initial disease status: Initial Diagnosis; Days to treatment start: 33 days; Days to treatment end: 87 days; Treatment outcome: Stable Disease; Reason treatment ended: Other; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Alemtuzumab + Pentostatin; Initial disease status: Initial Diagnosis; Days to treatment start: 89 days; Days to treatment end: 117 days; Treatment outcome: Stable Disease; Reason treatment ended: Other; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Alemtuzumab; Initial disease status: Initial Diagnosis; Days to treatment start: 136 days; Days to treatment end: 159 days; Treatment outcome: Stable Disease; Reason treatment ended: Death; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Stable Disease; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; adjuvant Radiation Therapy, NOS, postoperative; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.

Follow-up (2 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 80.
- Day 168 (end of treatment course 1): Disease response: With Tumor; Imaging type: PET; Imaging result: Positive.

Molecular and laboratory tests
- Lactate Dehydrogenase 746 U/L.
- Epstein-Barr Virus: Positive [Test analyte type: DNA].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 80.1 kg; Height: 180.5 cm; BMI: 24.6.
- Timepoint category: Prior to Diagnosis; Comorbidities: Psoriasis.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Pack years smoked: 30; Tobacco smoking quit year: 2013.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Sarcoma.

Biospecimens (2 samples)
- Sample RC-B65A-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample RC-B65A-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
